Gene-level copy-number profile of tumor specimen TCGA-D3-A8GO-06A from TCGA case TCGA-D3-A8GO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A8GO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.10b20847-367e-4140-bd6d-4a951317b124.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A8GO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff3beda3-2099-49c5-9c50-5e7cfd360cc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,539; copy number 1: 12,842; copy number 2: 39,394; copy number 3: 3,588; copy number 4: 970; copy number 5: 1,800; copy number 6: 136.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A8GO-06A-11D-A371-01): tumor purity 0.37, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1,015 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,426,742–238,452,250, 1 gene (within-gene range 0–2): ASB1.
- chr3:94,935,760–96,619,831, 13 genes: AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8.
- chr9:126,057,580–126,159,613, 1 gene: AL589923.1.
- chr9:134,992,958–135,252,708, 4 genes: AL353611.2, OLFM1, AL390778.1, AL390778.2.
- chr10:42,408,168–67,696,195, 358 genes (within-gene range 0–1) (broad region; genes not listed).
- chr11:123,723,914–124,274,581, 30 genes (within-gene range 0–2): ZNF202, OR6X1, RNU1-21P, OR6M1, OR6M2P, OR6M3P, TMEM225, OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1.
- chr14:56,759,379–88,555,007, 597 genes (within-gene range 0–1) (broad region; genes not listed).
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,936 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr7:70,972–71,713,600, 1,304 genes, copy number 5 (within-gene range 5–10) (broad region; genes not listed).
- chr7:71,913,738–71,942,468, 2 genes, copy number 5: RNA5SP232, AC005011.1.
- chr7:79,657,947–81,770,438, 22 genes, copy number 5 (within-gene range 3–5): AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:83,955,777–85,489,293, 12 genes, copy number 5 (within-gene range 4–5): SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr7:88,420,167–91,210,590, 32 genes, copy number 6 (within-gene range 4–6): AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1.
- chr7:108,883,975–142,106,747, 537 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:19,026,001–19,032,626, 2 genes, copy number 6 (within-gene range 2–6): GTF2IP3, AL137001.1.

Autosomal genes at a single copy (total copy number 1): 10,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
